TARGET case TARGET-10-PANSPW — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/929703da-64f8-57dd-b52b-d33bacf6d1ab

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 13 years; Vital status: Dead; Days to death: 870 days (2.4 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 13.1 years (4,798 days); Year of diagnosis: 2005; Days to last follow up: 870 days (2.4 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 113 days; Days to first event: 113 days; First event: Relapse.
- Days to follow up: 870 days (2.4 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2007.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Positive.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 58.9 ×10³/µL.
- Day 8: Bone Marrow blast count 14%.
- Day 15: Bone Marrow blast count 10%.
- Day 29: Bone Marrow blast count 7%; Minimal Residual Disease (Flow Cytometry) 24.4%.

Biospecimens (3 samples)
- Sample TARGET-10-PANSPW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PANSPW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PANSPW-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 870
- WBC at Diagnosis: 58.9
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 29: 24.4
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Positive
- BMA Blasts Day 8: 14
- BMA Blasts Day 15: 10
- BMA Blasts Day 29: 7
- Karyotype: 46,XY,t(9;22)(q34q11.2)/47,idem,+der(22)t(9;22)
- Down Syndrome: No
- DNA Index: 1
- Alternate Therapy: Chemotherapy
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: BCR-ABL1
